Gene-level copy-number profile of tumor specimen C3N-02764-02 (profiled together with C3N-02764-03) from CPTAC case C3N-02764, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 66.6 years (24,321 days).
Specimen C3N-02764-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5160d5b7-f579-4268-822e-62820d0c74f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02764-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/c25e9d01-85de-4d79-8ee1-3e8406f3f89b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 307; copy number 1: 218; copy number 2: 3,955; copy number 3: 10,523; copy number 4: 18,556; copy number 5: 6,579; copy number 6: 8,803; copy number 7: 5,350; copy number 8: 3,351; copy number 9: 264; copy number 10: 645; copy number 11: 33; copy number 12: 34; copy number 13: 241; copy number 14: 53; copy number 15: 1; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,271 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–146,036,746, 95 genes, copy number 9 (broad region; genes not listed).
- chr1:150,045,660–156,282,825, 353 genes, copy number 9–14 (broad region; genes not listed).
- chr1:157,059,232–158,100,262, 24 genes, copy number 12: SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52, AL357143.1, AL138900.1, LINC02772, AL138900.2, FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1.
- chr2:242,047,695–242,084,233, 1 gene, copy number 9 (within-gene range 5–9): LINC01880.
- chr5:58,198–42,191,523, 621 genes, copy number 10 (broad region; genes not listed).
- chr5:43,287,470–45,895,970, 32 genes, copy number 11: HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:32,549,940–32,589,848, 3 genes, copy number 12–17: RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr6:100,385,009–100,464,921, 2 genes, copy number 9: SIM1, SIM1-AS1.
- chr8:36,121,398–36,321,404, 7 genes, copy number 10: AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr9:5,193,339–5,470,566, 10 genes, copy number 9: AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274.
- chr9:61,190,003–61,627,683, 9 genes, copy number 12: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr10:99,651,595–99,732,112, 1 gene, copy number 9 (within-gene range 6–9): AL133353.2.
- chr10:99,702,558–100,009,947, 6 genes, copy number 9 (within-gene range 6–9): CUTC, COX15, ABCC2, NANOGP6, DNMBP, DNMBP-AS1.
- chr10:132,397,168–132,449,408, 4 genes, copy number 10: PWWP2B, AL451069.2, AL451069.3, LINC02870.
- chr17:28,269,203–29,057,216, 76 genes, copy number 9 (broad region; genes not listed).
- chr17:50,475,819–50,627,474, 10 genes, copy number 10 (within-gene range 8–10): AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3.
- chr19:19,254,748–19,546,659, 14 genes, copy number 13: AC138430.1, HAPLN4, AC138430.2, TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2.
- chr19:43,192,702–43,269,530, 3 genes, copy number 10: PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
